CPTAC case C3L-07959 — Stomach — Adenomas and Adenocarcinomas (CPTAC-3)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026), part of the Clinical Proteomic Tumor Analysis Consortium (CPTAC). Disease type: Adenomas and Adenocarcinomas; Primary site: Stomach. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/dcef42be-8418-40ab-a0f1-560dad57f366

Demographics
Sex at birth: female; Race: white; Year of birth: 1971; Vital status: Alive; Country of birth: Bulgaria.

Diagnoses (1)
1. Adenocarcinoma, NOS: ICD-O-3 morphology code: 8140/3; Tissue or organ of origin: Stomach, NOS; Site of resection or biopsy: Gastric antrum; Age at diagnosis: 49.5 years (18,089 days); Year of diagnosis: 2021; AJCC staging edition: 8th; AJCC clinical M: M1; AJCC pathologic T: T4a; AJCC pathologic N: N0; AJCC pathologic stage: Stage IV; Tumor grade: G3; Residual disease: R0; Days to last known disease status: 260 days; Progression or recurrence: no; Days to last follow up: 260 days; Tumor focality: Unifocal.
   Pathology details: Greatest tumor dimension: 10 cm; Lymph node involvement: Negative; Lymph nodes positive: 0; Lymph nodes tested: 3.
   Treatment given: Treatment type: Radiation Therapy, NOS; Days to treatment start: 20 days; Days to treatment end: 407 days (1.1 years); Treatment outcome: Complete Response.

Follow-up (1 entry)
- Days to follow up: 260 days; Disease response: Complete Response; ECOG performance status: 0.

Exposures
- Tobacco smoking status: Current Smoker; Pack years smoked: 14.5; Cigarettes per day: 10; Tobacco smoking onset year: 1991; Alcohol history: No; Alcohol intensity: Lifelong Non-Drinker.

Biospecimens (2 samples; slide percentages are pathologist estimates recorded by GDC per slide)
- Sample C3L-07959-05: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Antrum; Preservation method: Snap Frozen; Freezing method: LN2; Days to sample procurement: -12 days; Initial weight: 488 mg; Method of sample procurement: Tumor Resection; Diagnosis pathologically confirmed: Yes.
  Slide C3L-07959-25: Section location: Antrum; Percent tumor nuclei: 80; Percent necrosis: 7.
- Sample C3L-07959-31: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood Components NOS; Biospecimen anatomic site: Blood; Preservation method: Frozen; Freezing method: -20 (unit not recorded by GDC); Days to sample procurement: -12 days; Method of sample procurement: Blood Draw.
